Somatic mutation profile of tumor specimen MBCProject_5774_T1_WES (aliquot MBCProject_5774_T1_WES_1) from CMI case MBCProject_5774, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 64.8 years (23,667 days).
Specimen MBCProject_5774_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 270aeaac-20fd-49ab-8782-6f8d6b6c26c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5774_SALIVA (Saliva), aliquot MBCProject_5774_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c79aeeda-fcb0-4f24-878c-aa5a692b7a1c

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 5, Silent 5, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 56/216 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- AL139011.2 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 17/193 reads (9%) | catalogued as rs1165967149; called by muse, mutect2
- CLIP2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554732690; called by muse, mutect2, varscan2
- HUWE1 | c.10828C>T p.R3610W | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV53354347; called by muse, mutect2
- LRP6 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54384795; called by muse, mutect2
- PDSS1 | c.1051A>T p.M351L | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs777085672; called by muse, mutect2, varscan2
- RIMS2 | c.3146G>A p.R1049H (on ENST00000666250 / NM_001348490.2; = p.R857H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs995050197, COSV51669002; called by muse, mutect2, varscan2
- STAB1 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58741549; called by muse, mutect2, varscan2
- ZNF226 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760679907; called by mutect2, varscan2
- CDH1 | c.2429_2430del p.F810Yfs*2 | Frame Shift Del (DEL) | VAF 65/191 reads (34%) | called by mutect2, pindel, varscan2
- CENPI | c.1681A>C p.I561L | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNM3 | c.2536C>T p.P846S (on ENST00000355305 / NM_001350206.2; = p.P840S on NM_015569.5) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- GNRHR | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITCH | c.1644A>G p.I548M (on ENST00000262650 / NM_001257137.3; = p.I507M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, varscan2
- OR13C3 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- BTBD16 | c.162A>C p.P54= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- MDM2 | c.6G>A p.V2= | Silent (SNP) | VAF 31/371 reads (8%) | called by muse, mutect2
- PABPC4 | c.171C>G p.V57= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1266665390; called by muse, mutect2
- UNC93A | c.1362A>G p.Q454= | Silent (SNP) | VAF 29/309 reads (9%) | called by muse, varscan2
- ZKSCAN2 | c.936T>C p.H312= | Silent (SNP) | VAF 88/245 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.3185-173A>G | Intron (SNP) | VAF 88/195 reads (45%) | called by muse, mutect2, varscan2
- EDN3 | c.53-14T>A | Intron (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- IQCF2 | c.18+10A>G | Intron (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- METTL5 | c.591+106A>G | Intron (SNP) | VAF 12/101 reads (12%) | catalogued as rs1292649547, COSV53627506; called by muse, varscan2
- USP38 | c.1209+873A>G | Intron (SNP) | VAF 14/155 reads (9%) | catalogued as rs1356780771; called by muse, varscan2
